Gene-level copy-number profile of tumor specimen TCGA-GV-A3QI-01A from TCGA case TCGA-GV-A3QI, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 47.6 years (17,383 days).
Specimen TCGA-GV-A3QI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6f417a24-f868-4cd1-a60b-37df5f098c76.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GV-A3QI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8178d5e2-13a5-45e9-b544-7b60338eb031

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 101; copy number 1: 676; copy number 2: 11,834; copy number 3: 22,186; copy number 4: 20,066; copy number 5: 3,994; copy number 6: 320; copy number 7: 313; copy number 8: 11; copy number 10: 292; copy number 12: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GV-A3QI-01A-11D-A21Y-01): tumor purity 0.95, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,581,357–213,284,205, 12 genes (within-gene range 0–2): AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2, IKZF2, AC079610.1, LINC01953, AC079610.2, SPAG16-DT.
- chr5:55,935,095–56,233,330, 11 genes: IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2.
- chr10:74,151,202–74,709,963, 6 genes (within-gene range 0–2): ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–2): RB1.
- chr13:48,389,567–51,200,252, 63 genes (within-gene range 0–2) (broad region; genes not listed).
- chr13:97,221,434–97,394,120, 3 genes (within-gene range 0–2): MBNL2, AL161430.1, RNA5SP37.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 631 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:91,600,171–91,906,335, 3 genes, copy number 8 (within-gene range 3–8): AL714022.1, HSP90B3P, TGFBR3.
- chr1:158,831,351–170,085,208, 317 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr1:170,271,395–173,791,887, 71 genes, copy number 10–12 (broad region; genes not listed).
- chr1:173,808,489–173,808,622, 1 gene, copy number 12: Y_RNA.
- chr3:12,257,801–12,434,356, 3 genes, copy number 10: GSTM5P1, PPARG, AC091492.1.
- chr4:179,856,853–180,117,163, 3 genes, copy number 7: AC021193.1, AC108169.1, AC096747.1.
- chr5:131,423,921–132,013,199, 12 genes, copy number 7: RAPGEF6, AC008695.1, AC008497.1, FNIP1, ACTBP4, AC005593.1, MEIKIN, AC034228.3, AC034228.2, ACSL6, ACSL6-AS1, AC034228.1.
- chr9:14,395,791–14,594,200, 5 genes, copy number 8 (within-gene range 4–8): AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1.
- chr9:21,278,050–21,305,312, 2 genes, copy number 7: IFNA22P, IFNA5.
- chr9:36,336,396–37,034,268, 9 genes, copy number 7–8 (within-gene range 4–8): RNF38, MELK, AL442063.1, AL450267.2, MIR4475, PAX5, AL450267.1, MIR4540, MIR4476.
- chr19:32,127,334–36,422,534, 202 genes, copy number 7 (broad region; genes not listed).
- chr20:15,892,355–16,259,603, 3 genes, copy number 7: AL079338.1, AL161941.1, PPIAP17.

Autosomal genes at a single copy (total copy number 1): 676. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
